CCDI case PBBXDX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a1d092bc-53ae-4a8a-80e5-8d25b1572b63

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 14.3 years (5,211 days).

Biospecimens (3 samples)
- Sample 0DNDZG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNDZQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DNE0O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
